Somatic mutation profile of tumor specimen MMRF_1201_2_BM_CD138pos (aliquot MMRF_1201_2_BM_CD138pos_T1_KHS5U_L08845) from MMRF case MMRF_1201, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,577 days).
Specimen MMRF_1201_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3ac615b-a958-416e-827b-40841c9ebed4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1201_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1201_1_PB_WBC_C3_KBS5U_L02857; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5e9455c-47ac-4e4f-b7ca-02411d591493

The open-access MAF lists 227 somatic variants for this specimen: 91 protein-altering or splice-affecting, 28 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, 3'UTR 62, Intron 32, Silent 28, Nonsense Mutation 10, 5'UTR 5, Splice Site 4, 5'Flank 4, Splice Region 4, In Frame Del 3, Frame Shift Ins 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASP1 | c.338-1G>T p.X113_splice (on ENST00000436863 / NM_033292.4; = p.X92_splice on NM_001223.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV62057641; called by muse, mutect2, varscan2
- CECR2 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 45/90 reads (50%) | catalogued as rs1000953634, COSV52847831; called by muse, mutect2, varscan2
- CHRNA4 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs375524982, CM1212665, COSV64719127; called by muse, mutect2, varscan2
- CSMD3 | c.4339G>A p.V1447I (on ENST00000297405 / NM_001363185.1; = p.V1343I on NM_052900.3) | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as rs559028004; called by muse, mutect2, varscan2
- FECH | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs138138618; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- HIVEP2 | c.2674C>T p.R892* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as COSV50059289; called by muse, mutect2, varscan2
- HIVEP2 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV50074114; called by muse, mutect2
- HOXA1 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1207189382, COSV58029150; called by muse, mutect2, varscan2
- HTR1B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs750400332, COSV64051170; called by muse, mutect2, varscan2
- IGHJ5 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 34/44 reads (77%) | PolyPhen benign (0.086); catalogued as rs781822844; called by muse, varscan2
- IGHV2-70 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs368209907; called by muse, varscan2
- IGLL5 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs749763264, COSV73251006, COSV73251200; called by muse, mutect2, varscan2
- MEF2A | c.258+8A>G | Splice Region (SNP) | VAF 19/36 reads (53%) | catalogued as rs1220802225; called by muse, mutect2, varscan2
- MEGF8 | c.3422G>A p.W1141* (on ENST00000251268 / NM_001271938.2; = p.W1074* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as rs200096403, COSV52094945, COSV99236719; called by muse, mutect2, varscan2
- MICAL2 | c.2848-6G>C | Splice Region (SNP) | VAF 15/118 reads (13%) | catalogued as rs376516492; called by muse, mutect2, varscan2
- MYLIP | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.331); catalogued as COSV62767092; called by muse, mutect2, varscan2
- NEO1 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56071738; called by muse, mutect2
- PCDHGA4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV99542936; called by muse, mutect2, varscan2
- PCLO | c.15254G>A p.R5085Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569045178, COSV61643507, COSV61654875; called by muse, mutect2, varscan2
- PNMA2 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs769441970; called by muse, mutect2, varscan2
- RIT2 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 53/103 reads (51%) | catalogued as rs777127147, COSV100449455, COSV58676103; called by muse, mutect2, varscan2
- RNF150 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 15/409 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.405); catalogued as COSV60790460; called by muse, mutect2
- SCN11A | c.4433G>A p.R1478Q | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs758597298, COSV56577794; ClinVar: uncertain significance; called by muse, varscan2
- SORCS3 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV63818370; called by muse, mutect2
- SPEN | c.2370G>C p.K790N | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65367933; called by muse, mutect2
- TTN | c.93496G>A p.D31166N (on ENST00000591111; = p.D23742N on NM_003319.4) | Missense Mutation (SNP) | VAF 129/254 reads (51%) | PolyPhen benign (0.274); catalogued as COSV60236264; called by muse, mutect2, varscan2
- ANKRD44 | c.764T>G p.V255G | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- ARHGEF10 | c.2438T>C p.L813S (on ENST00000398564; = p.L788S on NM_014629.4) | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARID2 | c.627_629del p.F210del | In Frame Del (DEL) | VAF 28/68 reads (41%) | called by mutect2, varscan2
- ATAT1 | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, varscan2
- CAMK2D | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CBY3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CCDC14 | c.1868G>C p.G623A (on ENST00000488653; = p.G575A on NM_022757.5) | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.822); called by muse, mutect2
- CDHR1 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CHAF1A | c.1866C>A p.D622E | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- COL21A1 | c.2447A>C p.N816T | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CTU2 | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DDX42 | c.2023A>C p.N675H | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DPPA2 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- DTX1 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM83A | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGB | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.146); called by muse, mutect2
- FUBP1 | c.104_120+12del p.X35_splice | Splice Site (DEL) | VAF 20/57 reads (35%) | called by mutect2, varscan2
- GNAT3 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPR108 | c.1350+1G>A p.X450_splice (on ENST00000264080 / NM_001080452.1; = p.X208_splice on NM_020171.2) | Splice Site (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- H2BC8 | c.250T>G p.Y84D | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSD17B3 | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKC | c.322dup p.*108= | Frame Shift Ins (INS) | VAF 38/96 reads (40%) | called by mutect2, pindel, varscan2
- ITGA7 | c.1297G>C p.G433R (on ENST00000555728; = p.G389R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- JPH1 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIRREL2 | c.848C>G p.S283W | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- MACF1 | c.1326C>A p.N442K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- MPP7 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH13 | c.4980T>A p.H1660Q | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- NCOR1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- NETO1 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- NPM2 | c.271-7C>T | Splice Region (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- NR6A1 | c.1439A>G p.E480G (on ENST00000487099 / NM_033334.4; = p.E475G on NM_001489.5) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); called by muse, mutect2
- OGT | c.1803_1809delinsA p.F601_V603delinsL | In Frame Del (DEL) | VAF 64/66 reads (97%) | called by pindel, varscan2*
- OMA1 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- OPN4 | c.989A>C p.Y330S | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2
- OTUD7A | c.1798G>T p.D600Y (on ENST00000307050 / NM_001382637.1; = p.D593Y on NM_130901.3) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- PBXIP1 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 17/502 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2
- PIK3C2G | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2
- PIK3C2G | c.1727dup p.V578Gfs*5 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- PLCE1 | c.2092C>G p.P698A | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRD | c.3068dup p.N1023Kfs*23 | Frame Shift Ins (INS) | VAF 18/151 reads (12%) | called by mutect2, pindel, varscan2
- PTPRQ | c.2244A>G p.I748M (on ENST00000616559; = p.I706M on NM_001145026.2) | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRQ | c.2335T>C p.Y779H (on ENST00000616559; = p.Y737H on NM_001145026.2) | Missense Mutation (SNP) | VAF 96/160 reads (60%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); called by muse, varscan2
- PURA | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWWP2B | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- RBMXL2 | c.1008C>G p.Y336* | Nonsense Mutation (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- RHOT2 | c.222+6C>T | Splice Region (SNP) | VAF 72/249 reads (29%) | called by muse, mutect2, varscan2
- RSRP1 | c.416_430del p.Y139_R144delinsC | In Frame Del (DEL) | VAF 70/170 reads (41%) | called by pindel, varscan2
- SALL3 | c.3307G>C p.A1103P | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SBNO1 | c.1807T>A p.Y603N (on ENST00000420886; = p.Y602N on NM_018183.5) | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SEC61A1 | c.943A>C p.N315H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- SHTN1 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SLC35D1 | c.1032T>A p.N344K | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- SORL1 | c.6189G>A p.M2063I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPATA19 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 8/71 reads (11%) | called by pindel, varscan2*
- TFAP2C | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM14B | c.53A>C p.Y18S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNPO3 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- USP7 | c.2222A>T p.N741I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- YWHAZ | c.659T>A p.L220* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- ZNF189 | c.1792A>C p.T598P | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF217 | c.1877T>G p.L626* | Nonsense Mutation (SNP) | VAF 63/174 reads (36%) | called by muse, mutect2, varscan2
- ABL1 | c.165C>T p.L55= | Silent (SNP) | VAF 63/113 reads (56%) | catalogued as rs1028031620; called by muse, mutect2, varscan2
- AKAP6 | c.5136G>A p.P1712= | Silent (SNP) | VAF 98/179 reads (55%) | catalogued as rs375264170; called by muse, mutect2, varscan2
- CLRN1 | c.564A>T p.S188= (on ENST00000327047 / NM_174878.3; = p.S112= on NM_052995.2) | Silent (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- FAM53A | c.1158C>T p.A386= | Silent (SNP) | VAF 79/234 reads (34%) | catalogued as rs764172167; called by muse, mutect2, varscan2
- FBXO46 | c.1083G>C p.A361= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs1309475292; called by muse, mutect2, varscan2
- FHOD3 | c.1056C>T p.G352= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs142186343; called by muse, mutect2, varscan2
- FOXRED2 | c.1554G>A p.G518= | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as rs1214081729; called by muse, mutect2, varscan2
- GART | c.1350G>A p.L450= | Silent (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- GBF1 | c.2391A>C p.P797= (on ENST00000369983 / NM_001377137.1; = p.P796= on NM_004193.3) | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- GNAO1 | c.399C>T p.G133= | Silent (SNP) | VAF 93/186 reads (50%) | catalogued as rs556058539, COSV52612417; called by muse, mutect2, varscan2
- KAT2B | c.897T>A p.P299= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- KMT2C | c.13006A>C p.R4336= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- LRRC66 | c.2589C>T p.P863= | Silent (SNP) | VAF 54/197 reads (27%) | catalogued as rs928416573; called by muse, mutect2, varscan2
- MOSPD2 | c.933A>C p.S311= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- MYH1 | c.4653A>T p.A1551= | Silent (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- MYH6 | c.3696C>T p.D1232= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs779525060; called by muse, varscan2
- NHSL2 | c.1641G>A p.A547= (on ENST00000510661; = p.A913= on NM_001013627.2) | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs1348360882, COSV65452546; called by muse, mutect2, varscan2
- NIBAN1 | c.180G>A p.K60= | Silent (SNP) | VAF 11/206 reads (5%) | catalogued as rs1443797384; called by muse, mutect2
- OR4C12 | c.867T>C p.N289= | Silent (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- POLR3B | c.45G>A p.Q15= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- SLC9A4 | c.1278C>T p.Y426= | Silent (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- SNRNP200 | c.1542G>A p.L514= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- SPECC1 | c.2322C>T p.G774= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as rs1392496591; called by muse, mutect2
- STXBP5L | c.1707T>C p.P569= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- SYDE1 | c.1071C>T p.F357= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- TLX3 | c.234G>C p.V78= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- TMED1 | c.40C>T p.L14= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- TSC22D1 | c.189G>C p.L63= | Silent (SNP) | VAF 61/89 reads (69%) | called by muse, mutect2, varscan2
- ADGRL4 | c.*187G>T | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- ADI1 | chr2:3519543 G>A | 5'Flank (SNP) | VAF 6/70 reads (9%) | catalogued as rs972313444; called by muse, mutect2
- ALDH5A1 | c.*1579G>A | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- AMPH | c.1183-1410C>G | Intron (SNP) | VAF 74/133 reads (56%) | called by muse, mutect2, varscan2
- ANK1 | c.5395-1372A>T | Intron (SNP) | VAF 46/600 reads (8%) | called by muse, mutect2
- ATXN2L | c.*244G>A | 3'UTR (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- BCAN | c.1942+532G>T | Intron (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- BTG3 | c.*286C>T | 3'UTR (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- C12orf56 | c.*228C>A | 3'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- C12orf77 | n.612+213T>G | Intron (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- C1orf115 | c.*558G>A | 3'UTR (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- CACNA1D | c.2811+91C>T | Intron (SNP) | VAF 58/128 reads (45%) | catalogued as rs570064228; called by muse, mutect2, varscan2
- CACNB2 | c.120+235G>C | Intron (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- CALN1 | c.*5919A>C | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by mutect2, varscan2
- CAPN3 | c.*176G>A | 3'UTR (SNP) | VAF 30/658 reads (5%) | called by muse, mutect2
- CCDC58 | c.*174A>C | 3'UTR (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- CCNC | c.346+1079A>T | Intron (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- CCSAP | c.*1512A>T | 3'UTR (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- CDC37L1 | c.*494A>G | 3'UTR (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2, varscan2
- CDH8 | c.1536+90A>C | Intron (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- CFAP43 | c.1442+17T>C | Intron (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- CHCHD4 | c.-110C>A | 5'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- CHD2 | c.62+3316G>A | Intron (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- CHD8 | c.4921+14C>T | Intron (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- CHM | c.*1144T>C | 3'UTR (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
- CLDN1 | c.*320_*329del | 3'UTR (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- CLN8 | c.*4586C>T | 3'UTR (SNP) | VAF 32/77 reads (42%) | catalogued as rs538474232; called by muse, mutect2, varscan2
- CSK | c.722+28T>G | Intron (SNP) | VAF 57/171 reads (33%) | called by muse, mutect2, varscan2
- CUL1 | c.-87T>A | 5'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- DCBLD2 | c.*1826A>C | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- DENND6A | c.*2606T>A | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- DUS2 | c.-18-85C>G | Intron (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2
- EARS2 | c.139+117A>C | Intron (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- EN2 | c.*1058G>A | 3'UTR (SNP) | VAF 68/128 reads (53%) | called by muse, mutect2, varscan2
- F2RL2 | c.*43T>C | 3'UTR (SNP) | VAF 31/226 reads (14%) | called by muse, mutect2, varscan2
- FAM13A | c.605+562G>C | Intron (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- FAM155A | c.*247G>C | 3'UTR (SNP) | VAF 59/59 reads (100%) | called by muse, mutect2, varscan2
- FAM169B | n.614C>T | RNA (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85529921 G>C | 5'Flank (SNP) | VAF 43/80 reads (54%) | called by muse, mutect2, varscan2
- GALNT7 | c.*1558A>C | 3'UTR (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- GANC | c.*1309C>A | 3'UTR (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- GPX5 | c.*312C>T | 3'UTR (SNP) | VAF 60/124 reads (48%) | catalogued as rs966933727; called by muse, mutect2, varscan2
- HIRA | c.*468T>G | 3'UTR (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- HS3ST3B1 | c.*1791C>A | 3'UTR (SNP) | VAF 4/81 reads (5%) | called by muse, mutect2
- ID3 | c.*25+107G>T | Intron (SNP) | VAF 14/29 reads (48%) | called by muse, varscan2
- IER5L | c.*854C>T | 3'UTR (SNP) | VAF 16/134 reads (12%) | catalogued as rs1292748403; called by muse, mutect2, varscan2
- IL1RAP | c.*746C>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | catalogued as rs1441401088, COSV99299779; called by muse, mutect2
- KCNU1 | c.2010-16966C>A | Intron (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- KDM4C | c.435+340A>C | Intron (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- KIDINS220 | c.3586-43T>C | Intron (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- KMO | c.*209A>T | 3'UTR (SNP) | VAF 67/99 reads (68%) | called by muse, mutect2, varscan2
- LRRC58 | c.*891A>C | 3'UTR (SNP) | VAF 43/83 reads (52%) | called by muse, mutect2
- MEIS1 | c.-624_-621del | 5'UTR (DEL) | VAF 82/208 reads (39%) | catalogued as rs944697549; called by pindel, varscan2
- MIPOL1 | c.*626T>A | 3'UTR (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- MKRN2 | chr3:12584996 A>C | 3'Flank (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- MMP15 | c.*963G>A | 3'UTR (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- MND1 | c.*231T>C | 3'UTR (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- MPPED2 | c.*489C>T | 3'UTR (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- NR0B2 | c.*125T>A | 3'UTR (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- OS9 | c.481-97G>A | Intron (SNP) | VAF 3/46 reads (7%) | catalogued as rs1357817376; called by muse, mutect2
- PANX1 | c.*1049C>T | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- PCARE | c.*207C>A | 3'UTR (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- PDE1C | c.1892-11762A>T | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- PFDN6 | chr6:33295906 A>T | 3'Flank (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- PGR | c.*8C>T | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2
- PKN1 | c.1885-15C>G | Intron (SNP) | VAF 18/100 reads (18%) | catalogued as rs1485888754; called by muse, mutect2, varscan2
- POLR2B | chr4:56978687 A>T | 5'Flank (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- PPP2CA | c.*3139C>G | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2
- PPP4R1L | n.979+265A>C | Intron (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- PYGO1 | c.*2928C>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- RAB2A | c.*1405G>A | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- RYR2 | c.1708+1975G>C | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-3140G>T | Intron (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- SEMA5A | c.*2440G>A | 3'UTR (SNP) | VAF 16/98 reads (16%) | catalogued as rs988963741; called by muse, mutect2, varscan2
- SH3TC2 | c.3479-421T>G | Intron (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- SHPRH | c.*1031G>A | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*8603A>G | 3'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- SLC22A18AS | c.*35C>T | 3'UTR (SNP) | VAF 67/197 reads (34%) | catalogued as rs1353943167; called by muse, mutect2, varscan2
- SLC32A1 | c.*362G>A | 3'UTR (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- SLC35A4 | c.-430T>A | 5'UTR (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- SLFNL1 | c.-118-398T>G | Intron (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627429 T>A | 3'Flank (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- SMYD3 | c.531+989T>C | Intron (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-26 | n.33C>T | RNA (SNP) | VAF 8/65 reads (12%) | catalogued as rs774275910; called by muse, varscan2
- SNX3 | c.-68G>A | 5'UTR (SNP) | VAF 4/43 reads (9%) | catalogued as COSV57778029; called by muse, mutect2
- SOS2 | c.*374T>G | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- SPNS2 | c.*574T>C | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- ST8SIA2 | c.*4327T>C | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- STK32A | c.*2026C>T | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- STK33 | c.*121C>G | 3'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as COSV59400578; called by muse, mutect2
- STMN2 | c.*1131C>A | 3'UTR (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- SYNPO2 | c.*109_*110del | 3'UTR (DEL) | VAF 13/39 reads (33%) | called by pindel, varscan2
- TBL1X | c.*3288G>A | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2
- TLCD4 | c.*3543T>C | 3'UTR (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- TLE1 | c.1332-6716A>C | Intron (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- TLR2 | c.*389A>T | 3'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- TMA16 | chr4:163494510 T>C | 5'Flank (SNP) | VAF 53/135 reads (39%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.*1093C>A | 3'UTR (SNP) | VAF 71/537 reads (13%) | called by muse, mutect2, varscan2
- TP63 | c.1350-4959G>A | Intron (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- TPO | c.*398C>T | 3'UTR (SNP) | VAF 82/145 reads (57%) | called by muse, mutect2, varscan2
- TTF1 | c.*113G>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- UBE2B | c.*1T>A | 3'UTR (SNP) | VAF 15/237 reads (6%) | called by muse, mutect2
- UBE2B | c.*3G>A | 3'UTR (SNP) | VAF 14/231 reads (6%) | catalogued as COSV99530304; called by muse, mutect2
- UBE2L6 | c.*661C>G | 3'UTR (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- VPS8 | c.480+333G>A | Intron (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- YPEL5 | c.*1480A>T | 3'UTR (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- ZGRF1 | c.4697+46A>C | Intron (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- ZNF425 | c.*751T>A | 3'UTR (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
